Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3335, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3335-01A (Primary Tumor).

PHYSICIAN INFORMATION

SPECIMEN INFO

Collected: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Kidney (right): radical nephrectomy.

Renal cell carcinoma, clear cell type, grade 3-4 (Fuhman), 8.2 cm in greatest dimension, confined to the kidney, and without involvement of the peri pelvic fat.

Ureter and renal vessels at surgical margin negative for malignancy.

Inked surgical margin negative for malignancy.

Benign adrenal gland without pathologic findings.

Negative for lymphovascular invasion.

No lymph nodes submitted for evaluation.

AJCC cancer classification: T2NXMX.

Electronic Signature: [REDACTED]

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Right renal mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Right kidney and adrenal gland

SPECIMEN DATA

GROSS DESCRIPTION:

Received in one container labeled [REDACTED] right kidney and adrenal gland is a 597.5 gram right nephrectomy specimen, 11.5 x 9.8 x 6.0 cm. The specimen is covered by a gray capsule with a minimal amount of pericolic adipose tissue. A 5.5 x 0.4 cm long segment of ureter is identified at the hilum. On opening it is grossly uninvolved by lesion. A segment of artery and vein is identified. Each has a patent grossly uninvolved lumen. Extending from the hilum is a bulging firm mass, 8.2 x 6.1 x 6.0 cm. The specimen is sectioned to display a focally hemorrhagic lobular firm yellow cut surface. Grossly the lesion pushes against the renal capsule and pelvis. Grossly it does not perforate into the surrounding adipose tissue.

The remainder of the cut surface displays a congested parenchyma with poorly defined corticomedullary junction. The recognizable pelvis is lined by gray mucosa.

A 1.7 x 1.5 x 0.3 cm partial adrenal gland is attached and is 0.4 cm from the aforementioned lesion. The specimen has a normal appearing bright yellow cortex and red - brown medulla. It is grossly uninvolved by lesion. The perirenal adipose tissue is sectioned. Lymph nodes are not identified.

Separately submitted in the container is a 3.2 gram, 3.2 x 1.2 x 0.5 cm partial adrenalectomy specimen partially covered by lobular yellow adipose tissue. The specimen is inked and sectioned to display normal appearing cortex and medulla. Lesions are not identified.

Representative sections are submitted as follows: 1- ureteral and vascular margins; 2- lesion to pelvis; 3- lesion to inked margin; 4-7- lesion to uninvolved parenchyma; 8- uninvolved parenchyma; 9- lesion to adrenal gland; 10- separately submitted adrenal gland. The cassettes submitted for research labeled A, B, C and D [REDACTED]

Source: NCI Genomic Data Commons file 4550313f-21ec-4464-a8c9-6c3ccbda8765 (TCGA-A3-3335.A47DEB40-14C6-4B0B-A237-EC4594F4DDAE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).